Gene-level copy-number profile of tumor specimen TCGA-OR-A5KT-01A from TCGA case TCGA-OR-A5KT, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 44.4 years (16,217 days).
Specimen TCGA-OR-A5KT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.499cad1d-5d42-4834-8b88-42aec6523e07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3b1d215e-effe-45bb-9203-f92516c02b9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,462; copy number 2: 53,919; copy number 3: 339; copy number 4: 15; copy number 5: 180; copy number 6: 383; copy number 7: 180; copy number 8: 115; copy number 9: 7; copy number 10: 38; copy number 11: 55; copy number 12: 32; copy number 14: 95.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KT-01A-11D-A29H-01): tumor purity 0.65, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,085 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,713,411–43,181,506, 87 genes, copy number 5 (broad region; genes not listed).
- chr6:44,727,921–46,080,348, 11 genes, copy number 5 (within-gene range 3–5): AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5.
- chr6:47,368,943–48,111,078, 15 genes, copy number 6: B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1.
- chr12:43,560,784–43,806,328, 8 genes, copy number 6: AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr12:46,764,761–54,984,762, 394 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr12:55,330,043–55,757,264, 32 genes, copy number 14: OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1, OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11.
- chr12:55,761,550–55,762,628, 1 gene, copy number 14: AC073487.1.
- chr12:56,266,890–56,688,408, 29 genes, copy number 6: COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P.
- chr12:57,723,761–57,984,761, 25 genes, copy number 6: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,872,149–59,586,943, 11 genes, copy number 8: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P.
- chr12:59,812,102–63,006,902, 36 genes, copy number 6–9: AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1.
- chr12:65,169,583–65,966,291, 14 genes, copy number 10 (within-gene range 1–10): LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1.
- chr12:66,347,431–72,670,758, 114 genes, copy number 10–14 (broad region; genes not listed).
- chr12:73,115,957–73,208,317, 3 genes, copy number 7: AC090503.2, LINC02444, AC090503.1.
- chr12:82,358,528–84,449,878, 15 genes, copy number 6: METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr17:60,008,437–69,553,865, 281 genes, copy number 7–8 (within-gene range 2–10) (broad region; genes not listed).
- chr17:69,577,251–70,180,044, 9 genes, copy number 6–10 (within-gene range 1–10): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2.

Autosomal genes at a single copy (total copy number 1): 4,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
